Somatic mutation profile of tumor specimen 0DPHT6 from CCDI case PBCDGZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Retina; Age at diagnosis: 3.7 years (1,348 days).
Specimen 0DPHT6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d26a3b39-4896-4f48-b6ac-7430763a2dfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPHSW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7b09d23-da37-4011-beac-91c5ae5ad8ac

The open-access MAF lists 4 somatic variants for this specimen: 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTOF | c.2253G>A p.T751= (on ENST00000272371 / NM_194248.3; = p.T4= on NM_004802.4) | Silent (SNP) | VAF 80/268 reads (30%) | catalogued as rs201888333; ClinVar: uncertain significance; called by muse, varscan2
- TSC2 | c.1600-65G>A | Intron (SNP) | VAF 10/81 reads (12%) | called by muse, varscan2
- ZNF224 | c.142+99A>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- ZNF224 | c.142+100T>A | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
